Somatic mutation profile of tumor specimen MBCProject_5965_T1_WES (aliquot MBCProject_5965_T1_WES_1) from CMI case MBCProject_5965, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 27.3 years (9,973 days).
Specimen MBCProject_5965_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 688f61f7-ace1-4c31-9dd3-c785c8b2cfb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5965_SALIVA (Saliva), aliquot MBCProject_5965_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0271ed66-9352-426c-b210-80fefd6d6838

The open-access MAF lists 52 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Intron 3, 3'UTR 2, 5'UTR 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 92/203 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APCDD1 | c.609C>A p.N203K | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as rs956536247; called by muse, mutect2, varscan2
- AUTS2 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs772352925, COSV61423391; called by muse, mutect2, varscan2
- BBS12 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as rs1219749542; called by muse, mutect2, varscan2
- CUBN | c.9349C>T p.R3117C | Missense Mutation (SNP) | VAF 109/426 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs375906166, COSV64729645; called by muse, mutect2, varscan2
- ELF3 | c.1060T>G p.F354V | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100668951, COSV62838886; called by muse, mutect2, varscan2
- MID1 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 70/506 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV58197558; called by muse, mutect2, varscan2
- PLEKHG3 | c.409G>A p.A137T (on ENST00000394691; = p.A193T on NM_001308147.2) | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.329); catalogued as rs201431175; called by muse, mutect2, varscan2
- SLC5A5 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV55834491; called by muse, mutect2
- SNX31 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 95/647 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV61263881; called by muse, mutect2, varscan2
- SRGAP2 | c.3065G>A p.R1022Q (on ENST00000624873 / NM_001170637.4; = p.R1023Q on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/552 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.374); catalogued as rs782196124; called by muse, mutect2, varscan2
- ZAN | c.1796C>A p.T599N | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV61817938; called by muse, mutect2, varscan2
- AEBP1 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 44/569 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2
- CCNQ | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FBXO41 | c.1013G>C p.R338P | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEG1 | c.3559G>C p.D1187H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- HRC | c.1505C>A p.S502* | Nonsense Mutation (SNP) | VAF 79/251 reads (31%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.339A>C p.Q113H | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- IGHV4-61 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 58/536 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- KIFC2 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); called by muse, varscan2
- MCM5 | c.1936G>C p.V646L | Missense Mutation (SNP) | VAF 59/403 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO18B | c.2335A>G p.M779V | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR52B2 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR5R1 | c.679A>G p.R227G | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- OR5R1 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR9G1 | c.53C>G p.T18R | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PDZRN3 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SH2D1B | c.198+6A>G | Splice Region (SNP) | VAF 20/217 reads (9%) | called by muse, mutect2
- SLC9A9 | c.1355A>T p.N452I | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- TCP1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBED5 | c.1748A>T p.K583I | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZNF695 | c.536C>G p.T179S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ZNF713 | c.355A>G p.R119G (on ENST00000633730 / NM_001366796.2; = p.R132G on NM_182633.3) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ZSCAN18 | c.780G>T p.R260S | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALDH1L1 | c.1404C>A p.A468= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as COSV56409971; called by muse, mutect2, varscan2
- BRWD3 | c.2184G>A p.A728= | Silent (SNP) | VAF 66/311 reads (21%) | catalogued as rs369118921; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CDH22 | c.2079C>T p.D693= | Silent (SNP) | VAF 30/210 reads (14%) | called by muse, varscan2
- CFAP46 | c.1785C>T p.D595= | Silent (SNP) | VAF 33/172 reads (19%) | catalogued as rs780131996, COSV63953378, COSV63954895; called by muse, mutect2, varscan2
- DCTN1 | c.3546G>A p.S1182= | Silent (SNP) | VAF 69/477 reads (14%) | catalogued as rs149440626; called by muse, mutect2, varscan2
- EPHA4 | c.288G>A p.R96= | Silent (SNP) | VAF 31/250 reads (12%) | catalogued as COSV56029707, COSV99917771; called by muse, mutect2, varscan2
- FRMPD4 | c.3414C>A p.T1138= | Silent (SNP) | VAF 37/246 reads (15%) | catalogued as rs200324017, COSV66223322; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2223G>A p.V741= (on ENST00000265755 / NM_016328.3; = p.V726= on NM_005685.4) | Silent (SNP) | VAF 21/191 reads (11%) | called by muse, mutect2, varscan2
- MRC1 | c.690C>T p.Y230= | Silent (SNP) | VAF 129/441 reads (29%) | called by muse, mutect2, varscan2
- NLGN1 | c.2067G>A p.L689= | Silent (SNP) | VAF 53/200 reads (27%) | catalogued as rs1227261134; called by muse, mutect2, varscan2
- SPEG | c.1869G>A p.T623= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs1389064070; called by muse, mutect2, varscan2
- BICD1 | c.213+23C>A | Intron (SNP) | VAF 56/253 reads (22%) | called by muse, mutect2, varscan2
- FAM91A1 | c.*1511A>C | 3'UTR (SNP) | VAF 35/188 reads (19%) | called by muse, mutect2, varscan2
- MYH11 | c.5172-38G>T | Intron (SNP) | VAF 13/98 reads (13%) | called by muse, varscan2
- MYO1G | c.1949+88G>A | Intron (SNP) | VAF 39/423 reads (9%) | catalogued as rs762015453, COSV51855392; called by muse, mutect2
- NDRG4 | c.*42C>G | 3'UTR (SNP) | VAF 173/469 reads (37%) | called by muse, mutect2, varscan2
- TXLNG | c.-18G>A | 5'UTR (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- ZNF34 | c.-16C>G | 5'UTR (SNP) | VAF 27/309 reads (9%) | catalogued as rs1266373626; called by muse, mutect2
